Somatic mutation profile of tumor specimen HCM-BROD-0015-C25-01A (aliquot HCM-BROD-0015-C25-01A-01D-A78W-36) from HCMI case HCM-BROD-0015-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2; Age at diagnosis: 62.6 years (22,861 days).
Specimen HCM-BROD-0015-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54783e51-1c81-418c-aafc-da95ed85b9e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0015-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0015-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b0e707c-de78-4ee5-95cf-a91e60a48b45

The open-access MAF lists 108 somatic variants for this specimen: 66 protein-altering or splice-affecting, 2 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 57, RNA 19, 3'UTR 7, Intron 6, Missense Mutation 5, 5'UTR 3, 5'Flank 3, Silent 2, In Frame Ins 2, 3'Flank 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARGLU1 | c.760dup p.I254Nfs*26 | Frame Shift Ins (INS) | VAF 37/294 reads (13%) | catalogued as rs1214999704; called by mutect2, pindel, varscan2
- CHMP2A | c.591dup p.A198Sfs*10 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | catalogued as rs1568665166; called by mutect2, pindel
- H3-5 | c.109_111dup p.K37dup | In Frame Ins (INS) | VAF 53/80 reads (66%) | catalogued as rs879122881; called by pindel, varscan2
- IGHV3-15 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.195); catalogued as rs1555444012; called by muse, varscan2
- IGLV1-40 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as rs547836185; called by muse, varscan2
- ITGB5 | c.1019dup p.N340Kfs*34 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | catalogued as rs763839738; called by mutect2, varscan2
- KLK6 | c.718dup p.T240Nfs*45 | Frame Shift Ins (INS) | VAF 13/70 reads (19%) | catalogued as rs750767249; called by mutect2, pindel, varscan2
- MMADHC | c.544dup p.T182Nfs*2 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | catalogued as rs1308639482; called by mutect2, varscan2
- PHYKPL | c.1054dup p.I352Nfs*24 | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | catalogued as rs762471696; called by mutect2, varscan2
- PLEKHO1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV50311584; called by mutect2, varscan2
- POU5F1B | c.772_774dup p.Q258dup | In Frame Ins (INS) | VAF 16/22 reads (73%) | catalogued as rs1381831651; called by mutect2, pindel
- RCN1 | c.980dup p.N327Kfs*3 | Frame Shift Ins (INS) | VAF 9/101 reads (9%) | catalogued as rs1342710523; called by mutect2, pindel
- RDH14 | c.827dup p.K277Qfs*18 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs772840355; called by pindel, varscan2
- RNF19A | c.2016dup p.S673Ifs*5 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | catalogued as rs1225721197; called by pindel, varscan2
- RPEL1 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768037331, COSV101483095, COSV71503259; called by muse, varscan2
- SH3D21 | c.1969dup p.T657Nfs*30 (on ENST00000453908 / NM_001162530.2; = p.T546Nfs*30 on NM_024676.5) | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | catalogued as rs779458156; called by mutect2, pindel, varscan2
- SNX14 | c.1758dup p.E587Rfs*9 (on ENST00000314673 / NM_001350535.1; = p.E534Rfs*9 on NM_020468.5 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | catalogued as rs752429340; called by mutect2, pindel
- ANKHD1-EIF4EBP3 | c.4366dup p.R1456Kfs*20 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by pindel, varscan2
- ANKHD1-EIF4EBP3 | c.4385dup p.K1463Efs*13 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- ARCN1 | c.537dup p.A180Sfs*27 | Frame Shift Ins (INS) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- CEACAM5 | c.703+1_703+20del p.X235_splice | Splice Site (DEL) | VAF 10/72 reads (14%) | called by mutect2*, pindel
- COX20 | c.149dup p.L50Ffs*4 | Frame Shift Ins (INS) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- DUSP6 | c.984del p.N329Tfs*96 | Frame Shift Del (DEL) | VAF 54/90 reads (60%) | called by mutect2, pindel, varscan2
- ECD | c.1302dup p.E435Rfs*15 | Frame Shift Ins (INS) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- EID1 | c.499dup p.S167Ffs*15 | Frame Shift Ins (INS) | VAF 19/159 reads (12%) | called by mutect2, pindel
- EIF4A2 | c.681dup p.F228Ifs*18 | Frame Shift Ins (INS) | VAF 22/208 reads (11%) | called by mutect2, varscan2
- EIF5B | c.725dup p.R243Afs*3 | Frame Shift Ins (INS) | VAF 15/151 reads (10%) | called by mutect2, pindel
- ERN2 | c.1261dup p.T421Nfs*17 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2
- EXO5 | c.1113dup p.A372Sfs*21 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- FAM177A1 | c.149dup p.K51Efs*12 (on ENST00000382406 / NM_001289022.2; = p.K74Efs*12 on NM_173607.5) | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- FIP1L1 | c.1701dup p.S568Ifs*2 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- FPR1 | c.753dup p.L252Sfs*19 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- GJB2 | c.671dup p.P225Afs*32 | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- GOLGA4 | c.5141dup p.N1714Kfs*7 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- HMGN1 | c.147dup p.V50Sfs*18 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by pindel, varscan2
- INPP5B | c.2843dup p.N948Kfs*5 (on ENST00000373023; = p.N868Kfs*5 on NM_005540.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- ITPRID2 | c.1036dup p.I346Nfs*15 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.14680dup p.S4894Kfs*7 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- LSM1 | c.165dup p.Y56Ifs*3 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- MAP3K7 | c.1770dup p.Q591Tfs*41 (on ENST00000369329 / NM_145331.3; = p.Q564Tfs*41 on NM_003188.4) | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- MARK2 | c.675dup p.Y226Ifs*2 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- MBD4 | c.844dup p.S282Kfs*4 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by pindel, varscan2
- MIS12 | c.439dup p.I147Nfs*14 | Frame Shift Ins (INS) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- MTUS1 | c.1698dup p.A567Sfs*6 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- NBR1 | c.1619dup p.N540Kfs*5 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- NCK1 | c.734dup p.N245Kfs*9 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- PARL | c.1122dup p.G375Rfs*5 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by pindel, varscan2
- PCDHB14 | c.1175dup p.L393Pfs*14 | Frame Shift Ins (INS) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PLS3 | c.865dup p.I289Nfs*2 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- PPP4R3A | c.781dup p.I261Nfs*22 | Frame Shift Ins (INS) | VAF 2/16 reads (13%) | called by pindel, varscan2
- PRPF38B | c.1272dup p.H425Tfs*3 | Frame Shift Ins (INS) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- RAB11FIP1 | c.3837dup p.A1280Sfs*17 (on ENST00000330843 / NM_001002814.3; = p.A646Sfs*17 on NM_025151.5) | Frame Shift Ins (INS) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- RALA | c.431dup p.N144Kfs*4 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by pindel, varscan2
- RBM25 | c.1290dup p.R431Tfs*7 | Frame Shift Ins (INS) | VAF 9/81 reads (11%) | called by mutect2, pindel, varscan2
- RLF | c.5714dup p.T1906Dfs*3 | Frame Shift Ins (INS) | VAF 6/61 reads (10%) | called by pindel, varscan2
- RRBP1 | c.1617dup p.G540Rfs*16 | Frame Shift Ins (INS) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- SEC62 | c.411dup p.E138Rfs*9 | Frame Shift Ins (INS) | VAF 14/71 reads (20%) | called by mutect2, varscan2
- SELENOP | c.1124dup p.Sec376Vfs*? | Frame Shift Ins (INS) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- SENP6 | c.2493dup p.H832Tfs*7 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- SNX6 | c.1037dup p.N346Kfs*2 (on ENST00000652385; = p.N218Kfs*2 on NM_021249.5) | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | called by pindel, varscan2
- TBC1D9 | c.3734dup p.N1245Kfs*14 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- TEP1 | c.7524dup p.A2509Sfs*20 | Frame Shift Ins (INS) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- UBE2NL | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- VCAN | c.8265dup p.H2756Tfs*15 | Frame Shift Ins (INS) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- ZC3H11A | c.1273dup p.S425Kfs*13 | Frame Shift Ins (INS) | VAF 13/53 reads (25%) | called by mutect2, varscan2
- ZHX1 | c.1412dup p.T472Dfs*11 | Frame Shift Ins (INS) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- AC068631.2 | c.471T>C p.D157= | Silent (SNP) | VAF 242/242 reads (100%) | catalogued as rs908681427, COSV69713429; called by muse, varscan2
- EIF2S3B | c.1275C>T p.G425= | Silent (SNP) | VAF 72/72 reads (100%) | catalogued as rs780864273, COSV59370647; called by muse, varscan2
- AL590867.2 | n.52C>G | RNA (SNP) | VAF 1871/1872 reads (100%) | catalogued as rs375853555; called by muse, mutect2, varscan2
- ANXA2P2 | n.585C>T | RNA (SNP) | VAF 3458/3470 reads (100%) | catalogued as rs752927040; called by mutect2, varscan2
- ANXA2P2 | n.587A>G | RNA (SNP) | VAF 3598/3603 reads (100%) | catalogued as rs758587386; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502822 ins A | 5'Flank (INS) | VAF 36/342 reads (11%) | called by mutect2, pindel
- AP000769.3 | chr11:65505167 ins T | 5'Flank (INS) | VAF 16/139 reads (12%) | catalogued as rs752288826; called by mutect2, varscan2
- ARHGEF10L | c.*247dup | 3'UTR (INS) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- CEP295 | chr11:93733708 T>C | 3'Flank (SNP) | VAF 21/46 reads (46%) | called by muse, varscan2
- CHCHD2P9 | n.45A>G | RNA (SNP) | VAF 104/104 reads (100%) | catalogued as rs924781096; called by muse, varscan2
- CHCHD3 | c.170-10076A>C | Intron (SNP) | VAF 760/762 reads (100%) | catalogued as rs12673323, COSV52769412; called by mutect2, varscan2
- CLK2P1 | n.597A>G | RNA (SNP) | VAF 50/50 reads (100%) | catalogued as rs748569162; called by muse, varscan2
- EYS | c.1767-8511_1767-8509del | Intron (DEL) | VAF 24/24 reads (100%) | called by pindel, varscan2
- GBA3 | c.59-8514T>G | Intron (SNP) | VAF 221/221 reads (100%) | catalogued as rs538434925, COSV69742627; called by muse, varscan2
- HSP90AB3P | n.307A>G | RNA (SNP) | VAF 234/235 reads (100%) | catalogued as rs878954428; called by muse, varscan2
- HSP90AB3P | n.661A>G | RNA (SNP) | VAF 230/230 reads (100%) | catalogued as rs879027927; called by muse, varscan2
- HSP90AB3P | n.692A>G | RNA (SNP) | VAF 180/180 reads (100%) | catalogued as rs878942195; called by muse, varscan2
- HSP90AB3P | n.1001C>T | RNA (SNP) | VAF 269/269 reads (100%) | catalogued as rs878957678; called by muse, varscan2
- HSP90B3P | n.295A>G | RNA (SNP) | VAF 84/84 reads (100%) | catalogued as rs879227651; called by muse, varscan2
- IGHV1-2 | c.-16A>G | 5'UTR (SNP) | VAF 66/100 reads (66%) | catalogued as rs547595209; called by muse, varscan2
- IGHV3-74 | c.-3A>G | 5'UTR (SNP) | VAF 111/121 reads (92%) | catalogued as rs369715584; called by muse, varscan2
- LPIN2 | c.590+4947_590+4948insGA | Intron (INS) | VAF 10/16 reads (63%) | catalogued as rs758153451; called by pindel, varscan2
- MARCHF1 | c.-322-85400G>A | Intron (SNP) | VAF 72/72 reads (100%) | catalogued as rs878973250, COSV72275108, COSV72275201; called by muse, varscan2
- ME3 | c.920-7256del | Intron (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- MRRFP1 | n.553A>G | RNA (SNP) | VAF 18/18 reads (100%) | called by muse, varscan2
- PIPSL | n.2414A>G | RNA (SNP) | VAF 52/52 reads (100%) | catalogued as rs878949403; called by muse, varscan2
- PIPSL | n.1871A>G | RNA (SNP) | VAF 108/108 reads (100%) | catalogued as rs879091307; called by muse, varscan2
- PIPSL | n.1110C>T | RNA (SNP) | VAF 14/14 reads (100%) | called by muse, varscan2
- PSENEN | c.*27_*67del | 3'UTR (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- PTBP3 | chr9:112220175 ins T | 3'Flank (INS) | VAF 23/130 reads (18%) | catalogued as rs761818591; called by mutect2, pindel, varscan2
- RBMXL1 | c.-1A>C | 5'UTR (SNP) | VAF 14/25 reads (56%) | called by muse, varscan2
- RNF5P1 | n.273G>A | RNA (SNP) | VAF 52/52 reads (100%) | catalogued as rs879012319; called by muse, varscan2
- SGCB | c.*49dup | 3'UTR (INS) | VAF 4/23 reads (17%) | catalogued as rs754607880; called by pindel, varscan2
- SLC25A13 | c.*673dup | 3'UTR (INS) | VAF 4/46 reads (9%) | called by pindel, varscan2
- SLC25A13 | c.*129dup | 3'UTR (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- THYN1 | c.*57dup | 3'UTR (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- TMEM183B | n.590A>G | RNA (SNP) | VAF 40/42 reads (95%) | catalogued as rs2864778; called by muse, varscan2
- TMEM183B | n.370_372del | RNA (DEL) | VAF 8/28 reads (29%) | catalogued as rs1266738967; called by pindel, varscan2
- TMEM183B | n.238G>A | RNA (SNP) | VAF 9/25 reads (36%) | catalogued as rs397839818; called by muse, varscan2
- TSPYL4 | chr6:116258728 A>G | 5'Flank (SNP) | VAF 170/172 reads (99%) | catalogued as rs769261765, COSV70201985; called by muse, varscan2
- WASF4P | n.741A>G | RNA (SNP) | VAF 14/14 reads (100%) | catalogued as rs1449276246; called by muse, varscan2
- XIAP | c.*6017A>G | 3'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as rs192084571; called by muse, varscan2
